Somatic mutation profile of tumor specimen C3N-03069-01 (aliquot CPT0236340006) from CPTAC case C3N-03069, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 50.7 years (18,530 days).
Specimen C3N-03069-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43995452-5877-4b7d-836a-d298c06083bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03069-31 (Blood Derived Normal), aliquot CPT0236400002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a04da952-b589-46cf-a9db-adcf9d6261e1

The open-access MAF lists 90 somatic variants for this specimen: 60 protein-altering or splice-affecting, 19 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 19, Intron 5, Nonsense Mutation 3, 3'UTR 3, RNA 2, Frame Shift Del 2, 5'UTR 1, Splice Site 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 16/221 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- SCN2A | c.2810G>A p.R937H | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553579488, COSV51846923; ClinVar: pathogenic; called by muse, mutect2
- ANKLE1 | c.1684C>T p.R562W (on ENST00000394458; = p.R508W on NM_152363.6) | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs146466494; called by muse, mutect2, varscan2
- ANKRD27 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 50/386 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1441887281, COSV60128555; called by muse, varscan2
- CBLL1 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.844); catalogued as COSV56028861; called by muse, mutect2
- CD101 | c.1247C>G p.S416C | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV56717799; called by muse, mutect2, varscan2
- CDK5 | c.374G>C p.R125T | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99876960; called by muse, mutect2
- ELF2 | c.1568C>A p.P523H (on ENST00000379550 / NM_001331036.2; = p.P463H on NM_006874.4) | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV55496451; called by muse, mutect2
- GRIA1 | c.1988C>T p.T663M | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs752447548, COSV53605030; ClinVar: not provided; called by muse, mutect2, varscan2
- GTF3C1 | c.6097G>A p.A2033T | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.805); catalogued as rs1313121593; called by muse, mutect2, varscan2
- H2BC7 | c.72G>C p.K24N | Missense Mutation (SNP) | VAF 48/354 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV61911989; called by muse, mutect2, varscan2
- HECTD1 | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1566662068; called by muse, mutect2
- HS3ST2 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 25/337 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54465551; called by muse, mutect2
- KLK15 | c.403G>C p.G135R | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56826268; called by muse, mutect2
- PCDHA12 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 133/609 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.06); catalogued as rs560974692, COSV56482468; called by muse, mutect2, varscan2
- PKD1 | c.6434C>T p.A2145V | Missense Mutation (SNP) | VAF 42/446 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as rs1432925209; called by muse, mutect2
- PKHD1L1 | c.9961G>C p.V3321L | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV65744275; called by muse, mutect2
- PLCL1 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.05); catalogued as rs201197388; called by muse, mutect2, varscan2
- SETMAR | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs147670471, COSV100740822; called by muse, mutect2, varscan2
- SNAPC4 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 29/326 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.408); catalogued as COSV53733461; called by muse, mutect2
- SORCS3 | c.2200C>T p.R734* | Nonsense Mutation (SNP) | VAF 16/168 reads (10%) | catalogued as rs1386638840; called by muse, mutect2
- TMEM132C | c.2998C>T p.R1000C | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs765900766, COSV59418406; called by muse, mutect2, varscan2
- ZNF469 | c.3175A>G p.N1059D | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); catalogued as rs1180968437; called by muse, mutect2
- AC005324.2 | c.2849C>T p.A950V | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ACOX1 | c.377C>A p.S126* | Nonsense Mutation (SNP) | VAF 41/384 reads (11%) | called by muse, mutect2, varscan2
- ACSM4 | c.1402G>T p.V468F | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2
- ADGRG6 | c.2093T>C p.I698T | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- C5orf47 | c.339G>T p.K113N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CAVIN3 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.066); called by muse, mutect2
- COL11A2 | c.769A>T p.R257W | Missense Mutation (SNP) | VAF 16/470 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); called by muse, mutect2
- COL4A5 | c.2752_2767+2del | In Frame Del (DEL) | VAF 24/285 reads (8%) | called by mutect2, pindel
- COL5A2 | c.2732C>T p.P911L | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- DCLRE1B | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNHD1 | c.9166G>T p.A3056S | Missense Mutation (SNP) | VAF 39/344 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- DNM2 | c.236-2A>G p.X79_splice | Splice Site (SNP) | VAF 31/294 reads (11%) | called by muse, mutect2, varscan2
- EBP | c.471C>G p.G157= | Splice Region (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- ELAVL3 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- ESD | c.844G>C p.A282P | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- EXOC8 | c.211A>C p.I71L | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- FGF21 | c.190A>T p.R64W | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- HSF2BP | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- INA | c.558C>A p.S186R | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KDM7A | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 21/252 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.109); called by muse, mutect2
- KIAA0100 | c.3373C>A p.P1125T | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- MYO18A | c.6145C>G p.L2049V | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NELL1 | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NELL1 | c.683C>G p.P228R | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR2M5 | c.337T>G p.F113V | Missense Mutation (SNP) | VAF 29/481 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); called by muse, mutect2
- PALB2 | c.2067_2079del p.S691Rfs*14 | Frame Shift Del (DEL) | VAF 27/268 reads (10%) | called by mutect2, pindel, varscan2
- PARP12 | c.897T>G p.Y299* | Nonsense Mutation (SNP) | VAF 10/147 reads (7%) | called by muse, mutect2
- PDE4B | c.2082G>T p.K694N | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.19); called by muse, mutect2
- PI4KA | c.3773T>G p.M1258R | Missense Mutation (SNP) | VAF 48/430 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- PKD1 | c.6433G>T p.A2145S | Missense Mutation (SNP) | VAF 40/442 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.243); called by muse, mutect2
- RAPGEF6 | c.2139G>T p.R713S | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.297); called by muse, mutect2
- SAMD3 | c.396_412del p.I134Sfs*16 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | called by mutect2, pindel
- SIGLEC1 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 43/283 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- STUB1 | c.610C>A p.H204N | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- TMEM185B | c.284T>A p.L95H | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TUBG2 | c.138C>A p.D46E | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- USP45 | c.1749T>G p.I583M | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CPXM2 | c.465G>T p.T155= | Silent (SNP) | VAF 23/348 reads (7%) | catalogued as COSV99583062; called by muse, mutect2
- FOLR2 | c.228C>T p.Y76= | Silent (SNP) | VAF 21/509 reads (4%) | called by muse, mutect2
- IL16 | c.996C>T p.S332= | Silent (SNP) | VAF 27/413 reads (7%) | called by muse, mutect2
- ITIH6 | c.639C>A p.S213= | Silent (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2
- KIRREL1 | c.2073C>T p.N691= | Silent (SNP) | VAF 11/184 reads (6%) | called by muse, mutect2
- MRAS | c.438C>G p.T146= | Silent (SNP) | VAF 24/214 reads (11%) | called by muse, mutect2, varscan2
- MYBPC1 | c.693C>T p.I231= (on ENST00000550270 / NM_206820.2; = p.I256= on NM_002465.4) | Silent (SNP) | VAF 28/278 reads (10%) | called by muse, mutect2, varscan2
- NANOS2 | c.306G>C p.G102= | Silent (SNP) | VAF 28/340 reads (8%) | called by muse, mutect2
- NKTR | c.4296G>C p.R1432= | Silent (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- NLGN3 | c.1878T>C p.H626= (on ENST00000358741 / NM_181303.2; = p.H606= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/386 reads (8%) | called by muse, mutect2
- OR10AG1 | c.141G>A p.Q47= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- OR11A1 | c.405C>T p.L135= | Silent (SNP) | VAF 26/254 reads (10%) | catalogued as rs770429988; called by muse, mutect2
- PCLO | c.10413C>T p.S3471= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as rs766221241, COSV61665747; called by muse, mutect2
- PRKX | c.51C>G p.R17= | Silent (SNP) | VAF 21/138 reads (15%) | called by muse, mutect2, varscan2
- SMG1 | c.10858T>C p.L3620= | Silent (SNP) | VAF 19/250 reads (8%) | called by muse, mutect2
- SPARCL1 | c.804A>G p.Q268= | Silent (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
- TBXT | c.777T>C p.N259= | Silent (SNP) | VAF 30/235 reads (13%) | called by muse, mutect2, varscan2
- UGT1A3 | c.669T>A p.I223= | Silent (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- ZNF446 | c.855C>T p.G285= | Silent (SNP) | VAF 10/237 reads (4%) | called by muse, mutect2
- AEN | c.*890C>T | 3'UTR (SNP) | VAF 9/104 reads (9%) | called by muse, mutect2
- AKT2 | c.1176-42A>C | Intron (SNP) | VAF 42/374 reads (11%) | called by muse, mutect2, varscan2
- CDH5 | c.*2C>T | 3'UTR (SNP) | VAF 12/149 reads (8%) | catalogued as rs1267148293, COSV58516865; called by muse, mutect2
- CNTN6 | c.2705-9T>A | Intron (SNP) | VAF 17/134 reads (13%) | catalogued as rs752660380; called by muse, mutect2, varscan2
- DSCAML1 | c.*32G>A | 3'UTR (SNP) | VAF 20/216 reads (9%) | catalogued as rs541508985, COSV58395520; called by muse, mutect2
- GNPAT | c.-26A>G | 5'UTR (SNP) | VAF 38/505 reads (8%) | called by muse, mutect2
- LAMA3 | c.4998+1504C>G | Intron (SNP) | VAF 58/569 reads (10%) | called by muse, mutect2, varscan2
- LINC00917 | n.1528G>A | RNA (SNP) | VAF 34/291 reads (12%) | catalogued as rs1304411537; called by muse, mutect2, varscan2
- LIPC | c.88+4741C>T | Intron (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- MEN1 | c.927+38A>G | Intron (SNP) | VAF 31/265 reads (12%) | called by muse, mutect2
- OFCC1 | n.596C>A | RNA (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
